Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0XP, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0XP-01A (Primary Tumor).

TSS Patient ID:

Case #: DOB: Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: **Breast Cancer** Histological description: **Infiltrative ductal carcinoma**

Date of Procurement: Anatomic Site: **Breast** Tumor location: **Primary**

Tissue Specification: **Tumor** Specimen Matrix: **Tissue** Specimen Format: **OCT**

Container: **block** Type of Procurement: **surgery** Grade: **2**

T Stage: **2** N Stage: **1** M Stage: **0** Treatment: **none**

Treatment Details: **n/a**

Normal Sample

Anatomic Site: **Blood** Sample Type: **Normal** Type of Procurement: **blood draw**

Matrix: **Blood** Specimen Format: **frozen** Container: **tube**

Date of Procurement:

1CD-0-3

carcinoma, infiltrating duct, NOS 8500/3

Site: breast, NOS 050.9

hw 10/21/11

	hw 10/21/11	

Source: NCI Genomic Data Commons file 0c6c5bef-26b9-4669-bc35-4bdc7bf6e9a5 (TCGA-AN-A0XP.80E9B7CE-0D5D-4C01-A8E3-E6345BE145EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).